Somatic mutation profile of tumor specimen TCGA-G9-6363-01A (aliquot TCGA-G9-6363-01A-21D-1786-08) from TCGA case TCGA-G9-6363, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,480 days).
Specimen TCGA-G9-6363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09bf37e1-7018-4a03-8169-199d3c077bf6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6363-10A (Blood Derived Normal), aliquot TCGA-G9-6363-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f41e2426-50d0-46e2-ae41-7bd458310603

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 3, Nonsense Mutation 3, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF4 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 14/244 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65929284; called by muse, mutect2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2
- ACACB | c.2855T>A p.L952Q | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141709; called by muse, mutect2
- AGPAT2 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs1173020252, COSV65465354; called by muse, mutect2, varscan2
- ANKRD28 | c.1997C>G p.T666R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV67519506; called by muse, mutect2, varscan2
- ARSF | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63840526; called by muse, mutect2, varscan2
- CCDC144A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV61404222; called by muse, mutect2
- CCDC93 | c.949C>G p.R317G | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60119161, COSV60122319; called by muse, mutect2, varscan2
- CEP128 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV55385316; called by muse, mutect2, varscan2
- CLDN12 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs760443285, COSV55307618; called by muse, mutect2, varscan2
- DNAH2 | c.5081C>G p.S1694* | Nonsense Mutation (SNP) | VAF 36/450 reads (8%) | catalogued as COSV66723460; called by muse, mutect2
- ENOX1 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 41/152 reads (27%) | catalogued as COSV54910305, COSV54917884; called by muse, mutect2, varscan2
- EXOC2 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759386313, COSV57863496; called by muse, mutect2, varscan2
- FAM78B | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747327778, COSV57980401; called by muse, mutect2, varscan2
- FCAMR | c.1553A>G p.K518R (on ENST00000324852 / NM_001170631.2; = p.S251G on NM_032029.4) | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.076); catalogued as COSV61368843; called by muse, mutect2, varscan2
- FLII | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57499692; called by muse, mutect2, varscan2
- H3C8 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV59953484; called by muse, mutect2
- HSPBP1 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as rs535068399, COSV55334987; called by muse, mutect2, varscan2
- JAK1 | c.3174T>G p.F1058L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53809493; called by muse, mutect2
- JMJD4 | c.1136A>C p.N379T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59919332; called by muse, mutect2, varscan2
- KRT24 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as rs773246200, COSV52881274; called by muse, mutect2, varscan2
- KRTAP10-4 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV59972818; called by muse, mutect2
- PARP14 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV71735296; called by muse, mutect2, varscan2
- PRKCB | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV57792557; called by muse, mutect2
- TBCK | c.254G>C p.R85T | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV56760089; called by muse, mutect2, varscan2
- TBX5 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV59863675; called by muse, mutect2, varscan2
- TMEM132D | c.2069T>C p.I690T | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV67159923; called by muse, mutect2
- ZNF33A | c.2365A>T p.S789C (on ENST00000458705 / NM_006974.3; = p.S790C on NM_006954.2) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV56726864; called by muse, mutect2, varscan2
- CLASRP | c.1013_1015del p.E338del | In Frame Del (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2
- ADGRB3 | c.2202C>T p.N734= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV65410758; called by muse, mutect2, varscan2
- MAST2 | c.1926A>T p.L642= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV63620400; called by muse, mutect2, varscan2
- PPIL4 | c.1458A>G p.K486= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV53568146; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331643 G>A | 5'Flank (SNP) | VAF 23/92 reads (25%) | catalogued as rs749225387, COSV59810825; called by muse, mutect2, varscan2
